Surgical pathology report (de-identified scan), TCGA case TCGA-G4-6317, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Roswell Park, specimen TCGA-G4-6317-01A (Primary Tumor).

[page 1 of 2]
SPECIMENS:

- A. GALLBLADDER
- B. FALCIFORM
- C. LEFT LOBE LIVER

SPECIMEN(S):

- A. GALLBLADDER
- B. FALCIFORM
- C. LEFT LOBE LIVER

INTRAOPERATIVE CONSULTATION DIAGNOSIS:

- C. Left lobe liver: 1.1 cm nodule located 1.2 cm from closest margin.
Called to [REDACTED]

GROSS DESCRIPTION:

A. GALLBLADDER

Received fresh in a single container labeled and designated "gallbladder" and consists of gallbladder measuring 7.0 x 3.0 x 1.0 cm. The external surface of the gallbladder is pink-tan and grossly looks unremarkable. Cystic duct remnant measures 0.4 cm in length x 0.5 cm in diameter. Gallbladder is opened to reveal large brown to yellow mucosa. A small amount of yellow bile is in the gallbladder lumen. No mass lesions or calculi are identified. Gallbladder wall measures up to 0.2 cm in thickness. Representative sections of gallbladder wall and cystic duct are submitted in cassette A1.

B. FALCIFORM

Received fresh in a single container labeled and designated "falciform" and consists of piece of yellow-red fibroadipose tissue measuring 11.5 x 10.0 x 1.3 cm and weighs 80 gm. The specimen is serially sectioned and examined. No mass lesions or lymph node candidates are identified. Representative sections are submitted in cassette B1 and B2.

C. LEFT LOBE LIVER

Received fresh in a single container labeled and designated "left lobe liver" and consists of partial hepatectomy specimen weighing 290 gm and measuring 15.0 x 14.5 x 6.5 cm. The liver external surface is dark red. The surgical margin is grossly free of lesions. It is inked in black. Specimen is serially sectioned to reveal nodular mass/lesion measuring 1.1 x 1.5 x 1.2 cm. The lesion is ill-circumscribed and white-tan in color. It is located 1.2 cm from the closest resection margin. The rest of the liver parenchyma is dark red and grossly looks unremarkable. Representative sections are submitted for code of sections.

Code of sections:

- C1: lesion and closest resection margin
- C2: lesion
- C3: liver parenchyma, away from lesion

DIAGNOSIS:

A. GALLBLADDER, CHOLECYSTECTOMY:

- GALLBLADDER WITHOUT PATHOLOGIC ALTERATION.

B. SOFT TISSUE, FALCIFORM LIGAMENT, EXCISION:

- BENIGN FIBROADIPOSE TISSUE

C. LIVER, LEFT LOBE, PARTIAL HEPATECTOMY:

- METASTATIC ADENOCARCINOMA (1.5 CM) CONSISTENT WITH COLONIC PRIMARY.
- ADENOCARCINOMA 1.2 CM FROM THE RESECTION MARGIN.

CLINICAL HISTORY:

None given

PRE-OPERATIVE DIAGNOSIS:

Liver metastasis

[REDACTED]

[page 2 of 2]
[REDACTED]

Source: NCI Genomic Data Commons file 4baa45cb-4ac7-4f9d-850c-8127001ff56b (TCGA-G4-6317.852F4165-5450-4BA2-9042-1AC863F0CA90.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).